Somatic mutation profile of tumor specimen TCGA-67-3770-01A (aliquot TCGA-67-3770-01A-01W-0928-08) from TCGA case TCGA-67-3770, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.2 years (25,658 days).
Specimen TCGA-67-3770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 959dd170-dc8a-4167-894b-a6ab117f8d9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3770-10A (Blood Derived Normal), aliquot TCGA-67-3770-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6b0bda5-6719-4a69-a6b1-725815bfc49f

The open-access MAF lists 234 somatic variants for this specimen: 174 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 53, Nonsense Mutation 11, Splice Site 4, Frame Shift Del 4, RNA 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 1, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 138/487 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.12298G>A p.V4100I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758785338, COSV63665946; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 84/142 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- AC244197.3 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782543505, COSV61711429; called by muse, mutect2, varscan2
- ADCK2 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50780791; called by muse, mutect2, varscan2
- ADGRE1 | c.2344A>T p.S782C | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV51672684; called by muse, mutect2, varscan2
- ADGRG2 | c.1237C>A p.P413T (on ENST00000379869 / NM_001079858.3; = p.P410T on NM_005756.4) | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV61337766; called by muse, mutect2, varscan2
- ADGRV1 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 41/57 reads (72%) | catalogued as COSV67979447; called by muse, mutect2, varscan2
- AGMO | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV61106796; called by muse, mutect2, varscan2
- AHRR | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57083115, COSV57090941; called by muse, mutect2, varscan2
- AIFM1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 203/607 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs750418813, COSV54852416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.4492A>G p.I1498V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62339896; called by muse, mutect2, varscan2
- AKR1B15 | c.807C>A p.H269Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV71151127; called by muse, mutect2, varscan2
- ALDH8A1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774809603, COSV55640438; called by muse, mutect2, varscan2
- ALS2 | c.2805G>T p.W935C | Missense Mutation (SNP) | VAF 108/172 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51884423; called by muse, mutect2, varscan2
- ALS2 | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51884436; called by muse, mutect2, varscan2
- ANKS1B | c.1492A>C p.S498R | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.638); catalogued as COSV61337087; called by muse, mutect2, varscan2
- ARHGAP25 | c.574G>T p.G192C (on ENST00000409202 / NM_001007231.3; = p.G184C on NM_014882.3) | Missense Mutation (SNP) | VAF 264/616 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54899059, COSV54909603; called by muse, mutect2, varscan2
- ARL5B | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV66010949; called by muse, mutect2, varscan2
- ASPA | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53980179; called by mutect2, varscan2
- ASPM | c.2173G>T p.V725L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54125610; called by muse, mutect2
- B4GALNT1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV57541504; called by muse, mutect2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 26/204 reads (13%) | catalogued as rs745882580; called by mutect2, varscan2
- BPI | c.1381C>A p.P461T (on ENST00000262865; = p.P457T on NM_001725.3) | Missense Mutation (SNP) | VAF 124/246 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as COSV53404145; called by muse, mutect2, varscan2
- BTK | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 208/609 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58117681; called by muse, mutect2, varscan2
- C10orf71 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV60505264; called by muse, mutect2
- CD1C | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63805781; called by muse, mutect2, varscan2
- CDC42BPA | c.3709G>C p.D1237H (on ENST00000334218 / NM_001366019.2; = p.D1224H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62003766; called by muse, mutect2, varscan2
- CDH10 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 9/156 reads (6%) | catalogued as COSV52570994, COSV52571603; called by muse, mutect2
- CDH12 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 188/825 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66390334; called by muse, mutect2, varscan2
- CELF2 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as COSV64927774; called by muse, mutect2, varscan2
- CFAP54 | c.5107G>C p.E1703Q | Missense Mutation (SNP) | VAF 18/634 reads (3%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.732); catalogued as COSV61570903; called by muse, mutect2
- CMKLR1 | c.320T>C p.F107S (on ENST00000312143 / NM_001142344.2; = p.F105S on NM_004072.3) | Missense Mutation (SNP) | VAF 147/499 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56436566; called by muse, mutect2, varscan2
- CNTN6 | c.2520C>A p.V840= | Splice Region (SNP) | VAF 38/267 reads (14%) | catalogued as COSV63163479; called by muse, mutect2, varscan2
- COL4A1 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as COSV65422129; called by muse, mutect2, varscan2
- COQ7 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as COSV58981337; called by muse, mutect2, varscan2
- CSMD3 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.368); catalogued as COSV52113654; called by muse, mutect2, varscan2
- CYP4F22 | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.77); catalogued as COSV54106888; called by muse, mutect2, varscan2
- DBX1 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV57053600; called by muse, mutect2, varscan2
- DMGDH | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772215706, COSV54861015; called by muse, mutect2, varscan2
- DNAH7 | c.11271G>T p.L3757F | Missense Mutation (SNP) | VAF 624/1007 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56753895; called by muse, mutect2, varscan2
- DNAH9 | c.8404G>T p.D2802Y | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52336870; called by muse, mutect2
- DSC2 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as COSV51861802; called by muse, mutect2, varscan2
- ELAVL2 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 125/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56358068, COSV56371535; called by muse, mutect2, varscan2
- EOLA2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | catalogued as COSV62207032; called by muse, mutect2, varscan2
- EP400 | c.4901G>T p.R1634L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57764487; called by muse, mutect2, varscan2
- EPB41L4B | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65795749; called by muse, mutect2, varscan2
- EPX | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772930951, COSV56595235; called by muse, mutect2, varscan2
- EXOSC7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55555557, COSV99651746; called by muse, mutect2, varscan2
- FAM71A | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV54234778; called by muse, mutect2, varscan2
- FAT3 | c.5760C>G p.Y1920* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV53081309; called by muse, mutect2, varscan2
- FIZ1 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV55607184; called by muse, mutect2
- GABBR2 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV52294711; called by muse, mutect2, varscan2
- GABRA5 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV59476292; called by muse, mutect2, varscan2
- GALNTL5 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV67179419; called by muse, mutect2, varscan2
- GHRHR | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58195710; called by muse, mutect2, varscan2
- GPR142 | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV59518721, COSV59519491, COSV99046011; called by muse, mutect2, varscan2
- GRAMD1A | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58765999; called by muse, mutect2, varscan2
- HEPH | c.1894C>T p.P632S (on ENST00000343002; = p.P365S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57959928; called by muse, mutect2, varscan2
- IGSF10 | c.5038A>T p.I1680F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56782188; called by muse, mutect2
- IL1RAPL2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV61144728; called by muse, mutect2, varscan2
- IRX6 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51859386; called by muse, mutect2, varscan2
- ITGAM | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV54934441; called by muse, mutect2, varscan2
- ITPRID1 | c.2680C>T p.L894F | Missense Mutation (SNP) | VAF 186/535 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV60070763; called by muse, mutect2, varscan2
- KDM3B | c.1355G>A p.G452D | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs988725742, COSV58688398; called by muse, mutect2, varscan2
- KIAA1109 | c.9907C>A p.H3303N | Missense Mutation (SNP) | VAF 189/614 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52664059; called by muse, mutect2, varscan2
- KIF2B | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52127518, COSV52133387; called by muse, mutect2, varscan2
- KLHL34 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1202080387, COSV65278792; called by muse, mutect2
- KMT2C | c.1110C>A p.C370* | Nonsense Mutation (SNP) | VAF 916/3628 reads (25%) | catalogued as COSV51341131; called by mutect2, varscan2
- KRT32 | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56785641, COSV56788097; called by muse, mutect2, varscan2
- LAX1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV65848824; called by muse, mutect2, varscan2
- LILRA6 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV54430896; called by muse, varscan2
- MAGEB3 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV64396791; called by muse, mutect2, varscan2
- MAP7D3 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 54/161 reads (34%) | catalogued as COSV60170195; called by muse, mutect2, varscan2
- MARCO | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 177/265 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV59052225; called by muse, mutect2, varscan2
- MAST1 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52241892; called by mutect2, varscan2
- MAST1 | c.1907-1G>T p.X636_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV52241916; called by muse, mutect2, varscan2
- MCM3AP | c.1579A>G p.S527G | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52436721; called by muse, mutect2, varscan2
- MKI67 | c.5200A>T p.K1734* | Nonsense Mutation (SNP) | VAF 53/146 reads (36%) | catalogued as COSV64072822; called by muse, mutect2, varscan2
- MTR | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63963997; called by muse, mutect2, varscan2
- MUC16 | c.37207G>T p.E12403* | Nonsense Mutation (SNP) | VAF 535/1916 reads (28%) | catalogued as COSV67448438; called by muse, mutect2, varscan2
- MUC16 | c.16375C>A p.L5459M | Missense Mutation (SNP) | VAF 193/668 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV67448443; called by muse, mutect2, varscan2
- MUC17 | c.6864C>G p.H2288Q | Missense Mutation (SNP) | VAF 157/434 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60281556; called by muse, mutect2, varscan2
- MUC17 | c.7369C>A p.P2457T | Missense Mutation (SNP) | VAF 137/705 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1388738229, COSV60281565, COSV60289466; called by muse, mutect2, varscan2
- MYH7 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs397516199, COSV62516785; ClinVar: uncertain significance; called by mutect2, varscan2
- MYO3B | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 131/207 reads (63%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.774); catalogued as COSV58695984; called by muse, mutect2, varscan2
- MYPN | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489529278, COSV62731883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.2075C>A p.T692N (on ENST00000396087 / NM_001244963.2; = p.T669N on NM_145117.5) | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV62316435; called by muse, mutect2, varscan2
- NBPF26 | c.2637C>T p.P879= (on ENST00000620612; = p.P617= on NM_001351372.1) | Splice Region (SNP) | VAF 513/780 reads (66%) | catalogued as rs1553272258; called by muse, mutect2, varscan2
- NCKAP1L | c.2726C>A p.T909N | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53203925; called by muse, mutect2, varscan2
- NEK4 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV51778966; called by muse, mutect2, varscan2
- NFATC2 | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65353515; called by muse, mutect2, varscan2
- NKX6-1 | c.1047C>G p.S349R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55684154, COSV99880191; called by muse, mutect2, varscan2
- NLGN4X | c.2129G>C p.R710P | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52006443, COSV52018823; called by muse, mutect2, varscan2
- NLGN4X | c.1581G>T p.W527C | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52006217; called by muse, mutect2
- NLN | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66765079; called by muse, mutect2, varscan2
- NLRP13 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 101/189 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61620289; called by muse, mutect2, varscan2
- NOLC1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV64180007; called by muse, mutect2, varscan2
- NR0B1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.067); catalogued as COSV66763659; called by muse, mutect2
- NTRK1 | c.1501+1G>T p.X501_splice | Splice Site (SNP) | VAF 30/76 reads (39%) | catalogued as COSV62323771; called by muse, mutect2, varscan2
- NUP43 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.249); catalogued as COSV61188945; called by muse, mutect2, varscan2
- OLFML2B | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV54194567; called by muse, mutect2, varscan2
- OPN5 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV55244401; called by muse, mutect2, varscan2
- OPRL1 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs148381492, COSV61091020; called by muse, mutect2
- OR10A4 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65841720; called by muse, mutect2, varscan2
- OR10H4 | c.430C>G p.H144D | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV59061280; called by muse, mutect2, varscan2
- OR14A16 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 124/379 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV62926198; called by muse, mutect2, varscan2
- OR14I1 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61199111; called by muse, mutect2, varscan2
- OR2T2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373307163; called by muse, mutect2, varscan2
- OR2T2 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100737633, COSV61618684; called by muse, mutect2, varscan2
- OR2W3 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV64456197, COSV64457091, COSV64457924; called by muse, mutect2, varscan2
- OR4K15 | c.116T>A p.L39Q (on ENST00000305051; = p.L15Q on NM_001005486.1) | Missense Mutation (SNP) | VAF 267/632 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV59300506; called by muse, mutect2, varscan2
- OR51M1 | c.772T>A p.C258S | Missense Mutation (SNP) | VAF 212/750 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV60783900; called by muse, mutect2
- OR56A1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 187/539 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV57361868; called by muse, mutect2, varscan2
- OR5H14 | c.415G>T p.G139* | Nonsense Mutation (SNP) | VAF 268/672 reads (40%) | catalogued as COSV71193484, COSV71193550; called by muse, varscan2
- OR5T2 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 361/991 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV57588012; called by muse, mutect2, varscan2
- OTUD7B | c.2364G>T p.W788C | Missense Mutation (SNP) | VAF 119/380 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.416); catalogued as COSV64915314; called by muse, mutect2, varscan2
- PARVG | c.433del p.A145Pfs*30 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as COSV63561833; called by mutect2, pindel, varscan2
- PBRM1 | c.4729G>T p.G1577C (on ENST00000296302 / NM_001366071.2; = p.G1470C on NM_018313.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV56263430, COSV56303941; called by muse, mutect2, varscan2
- PCDH19 | c.3367C>A p.H1123N (on ENST00000373034 / NM_001184880.2; = p.H1075N on NM_020766.3) | Missense Mutation (SNP) | VAF 314/913 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV55258331; called by muse, mutect2, varscan2
- PCDHGA2 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV53906919; called by muse, mutect2, varscan2
- PCLO | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV61618634; called by muse, mutect2, varscan2
- PDE1C | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 136/495 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100371989, COSV100372115; called by muse, mutect2, varscan2
- PDE4DIP | c.6765G>T p.W2255C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57679536; called by muse, mutect2, varscan2
- PDZD2 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56852185; called by muse, mutect2, varscan2
- PMPCB | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV50785576; called by muse, mutect2, varscan2
- PNLIPRP1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV62610953; called by muse, mutect2, varscan2
- PPIP5K2 | c.2309A>G p.E770G | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV58603075; called by muse, mutect2, varscan2
- PPP2R5B | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV51209778; called by muse, mutect2, varscan2
- PRICKLE2 | c.1124C>A p.S375Y (on ENST00000295902; = p.S319Y on NM_198859.4) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55763304, COSV55766376; called by muse, mutect2, varscan2
- PRKAA1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV57183124; called by muse, mutect2, varscan2
- QPRT | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV54879186; called by muse, mutect2, varscan2
- RAD51AP2 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV67587352, COSV67587430; called by muse, mutect2
- RALGAPB | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53434876, COSV99485740; called by muse, mutect2, varscan2
- RASA2 | c.451-1G>T p.X151_splice | Splice Site (SNP) | VAF 81/197 reads (41%) | catalogued as COSV53936847, COSV53942693; called by muse, mutect2, varscan2
- RIMS2 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 374/1726 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68470559, COSV68477039; called by muse, mutect2, varscan2
- RIOK2 | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51611077; called by muse, mutect2, varscan2
- RMND5A | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 159/455 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV52152856; called by muse, mutect2, varscan2
- SEC24D | c.2417G>T p.R806L | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV54877271; called by muse, mutect2, varscan2
- SH3PXD2A | c.3147G>C p.Q1049H (on ENST00000369774 / NM_001365079.1; = p.Q1021H on NM_014631.2) | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV60115938; called by muse, mutect2, varscan2
- SIGLEC1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52459462; called by muse, mutect2, varscan2
- SIGLEC14 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 84/144 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55777846; called by muse, mutect2, varscan2
- SLC19A1 | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV60586835; called by muse, mutect2
- SLC30A9 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 146/450 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV52554271; called by muse, mutect2, varscan2
- SLC7A11 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54928239; called by muse, mutect2, varscan2
- SMG1 | c.10868G>T p.R3623L | Missense Mutation (SNP) | VAF 612/1744 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV67169680, COSV67169705; called by muse, mutect2, varscan2
- SPTA1 | c.5760del p.W1920* | Frame Shift Del (DEL) | VAF 177/619 reads (29%) | catalogued as COSV63751919; called by mutect2, pindel, varscan2
- SPTA1 | c.3322G>T p.V1108L | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV63749644; called by muse, mutect2, varscan2
- SSTR4 | c.386A>T p.N129I | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54797190; called by muse, mutect2, varscan2
- STX18 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV60371895; called by muse, mutect2, varscan2
- TEKT1 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 221/495 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100106125; called by muse, mutect2, varscan2
- TEKT1 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 221/497 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100106127; called by muse, mutect2, varscan2
- TIFAB | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV72345680; called by muse, mutect2, varscan2
- TLL2 | c.1755C>A p.H585Q | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV63571032; called by muse, mutect2, varscan2
- TLR6 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 81/257 reads (32%) | catalogued as COSV67935016; called by muse, mutect2, varscan2
- TMEM117 | c.991G>C p.G331R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896173, COSV56921533; called by muse, mutect2, varscan2
- TMEM130 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 127/323 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.661); catalogued as rs369734825; called by muse, mutect2, varscan2
- TMPRSS12 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 336/934 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68255845; called by muse, mutect2, varscan2
- TNR | c.2708T>G p.V903G | Missense Mutation (SNP) | VAF 125/420 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.192); catalogued as COSV54873045, COSV54919251; called by muse, mutect2, varscan2
- TNRC6C | c.2522G>A p.G841D | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV56941180, COSV56945531; called by muse, mutect2
- USP11 | c.2754G>T p.E918D (on ENST00000218348; = p.E875D on NM_001371072.1) | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV54472686, COSV54473254; called by muse, mutect2, varscan2
- VCX | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58232455; called by mutect2, varscan2
- XPO5 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54827771; called by muse, mutect2
- ZFC3H1 | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); catalogued as COSV66430538, COSV66432305; called by muse, mutect2, varscan2
- ZMIZ1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57890520; called by muse, mutect2
- ZNF208 | c.3776G>T p.G1259V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285650109, COSV68101522; called by muse, mutect2, varscan2
- ZNF479 | c.975C>G p.C325W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV58636343; called by muse, mutect2, varscan2
- ZNF611 | c.1749C>G p.C583W | Missense Mutation (SNP) | VAF 530/1002 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as COSV60539626, COSV60543488; called by muse, mutect2, varscan2
- GJA10 | c.1620del p.K540Nfs*? | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- MAGED2 | c.1434del p.M479Wfs*5 | Frame Shift Del (DEL) | VAF 63/246 reads (26%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1036dup p.S346Kfs*78 | Frame Shift Ins (INS) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- RBM10 | c.1891dup p.A631Gfs*42 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- SYNE2 | c.4911_4913del p.Y1638del | In Frame Del (DEL) | VAF 59/160 reads (37%) | called by mutect2, pindel, varscan2
- TPTE | c.1361T>A p.L454H (on ENST00000618007 / NM_199261.4; = p.L436H on NM_199259.4) | Missense Mutation (SNP) | VAF 69/370 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABCA5 | c.858A>G p.T286= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV67015912; called by muse, mutect2, varscan2
- ATP2B2 | c.2994C>T p.N998= (on ENST00000352432; = p.N964= on NM_001683.5) | Silent (SNP) | VAF 135/578 reads (23%) | catalogued as rs759463804, COSV59490670; called by muse, mutect2, varscan2
- AVPR2 | c.495C>A p.A165= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV61685846; called by muse, mutect2, varscan2
- C10orf53 | c.228C>A p.T76= | Silent (SNP) | VAF 97/291 reads (33%) | catalogued as COSV65108493; called by muse, mutect2, varscan2
- CACNA1E | c.420G>A p.G140= | Silent (SNP) | VAF 159/551 reads (29%) | catalogued as COSV62383938; called by muse, mutect2, varscan2
- CAPN6 | c.480T>C p.N160= | Silent (SNP) | VAF 158/499 reads (32%) | catalogued as COSV60694028; called by muse, mutect2, varscan2
- CCDC198 | c.99T>C p.F33= | Silent (SNP) | VAF 104/361 reads (29%) | catalogued as COSV53601451; called by muse, mutect2, varscan2
- CDH23 | c.306C>A p.T102= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV54925852; called by muse, mutect2, varscan2
- CHD5 | c.1339C>T p.L447= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV52408983; called by muse, mutect2
- COG5 | c.1650G>T p.V550= | Silent (SNP) | VAF 231/671 reads (34%) | catalogued as COSV51743635; called by muse, mutect2, varscan2
- CPS1 | c.2199A>G p.P733= | Silent (SNP) | VAF 222/320 reads (69%) | catalogued as rs780079490, COSV51803421; called by muse, mutect2, varscan2
- CSMD2 | c.891C>T p.R297= | Silent (SNP) | VAF 363/499 reads (73%) | catalogued as rs143306375; called by muse, mutect2, varscan2
- CSMD3 | c.627C>T p.I209= | Silent (SNP) | VAF 100/473 reads (21%) | catalogued as COSV52113674; called by muse, mutect2
- CT83 | c.189T>C p.S63= | Silent (SNP) | VAF 191/733 reads (26%) | catalogued as COSV64140810; called by muse, mutect2, varscan2
- DDX49 | c.645C>T p.T215= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs776218879, COSV53229646; called by muse, mutect2, varscan2
- ENO3 | c.342G>T p.V114= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV56697277; called by muse, mutect2, varscan2
- F8 | c.3672C>A p.I1224= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as COSV64270131; called by muse, mutect2, varscan2
- FAT3 | c.13311C>A p.S4437= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV53081326; called by muse, mutect2, varscan2
- FLNC | c.7434C>A p.I2478= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV57951454; called by muse, mutect2, varscan2
- FOXP2 | c.555G>A p.Q185= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs1017119086, COSV63481978; called by muse, mutect2, varscan2
- GOLIM4 | c.2070A>G p.S690= | Silent (SNP) | VAF 144/594 reads (24%) | catalogued as COSV58328184; called by muse, mutect2, varscan2
- GRIN3A | c.3024C>A p.P1008= | Silent (SNP) | VAF 138/265 reads (52%) | catalogued as COSV62451310; called by muse, mutect2, varscan2
- HAUS4 | c.180A>G p.L60= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV52826805, COSV52826907; called by muse, mutect2, varscan2
- HEG1 | c.2469C>T p.S823= | Silent (SNP) | VAF 74/217 reads (34%) | catalogued as COSV60759854; called by muse, mutect2, varscan2
- HERC2 | c.8964A>G p.T2988= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as rs1019855385, COSV55310351; called by muse, mutect2, varscan2
- IGSF10 | c.3699G>A p.V1233= | Silent (SNP) | VAF 170/452 reads (38%) | catalogued as rs557184605, COSV56782197; called by muse, mutect2, varscan2
- IHH | c.990C>T p.A330= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV55392810; called by muse, mutect2, varscan2
- IP6K2 | c.876C>T p.F292= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV53659940; called by muse, mutect2, varscan2
- KRT3 | c.300C>A p.G100= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV58814817; called by muse, mutect2, varscan2
- KRT85 | c.141G>A p.G47= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV57736101; called by muse, mutect2, varscan2
- MAGEA12 | c.927T>C p.F309= | Silent (SNP) | VAF 208/647 reads (32%) | catalogued as COSV63294248; called by muse, mutect2, varscan2
- MAGEE1 | c.201C>T p.S67= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV63909010; called by muse, mutect2, varscan2
- MED24 | c.225C>T p.Y75= | Silent (SNP) | VAF 87/310 reads (28%) | catalogued as rs748538779, COSV62417415; called by muse, mutect2, varscan2
- NEU3 | c.387G>A p.K129= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV53635769; called by muse, mutect2, varscan2
- NIBAN3 | c.342G>T p.R114= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56305765; called by muse, mutect2, varscan2
- NRK | c.4107T>C p.Y1369= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV54590957; called by muse, mutect2, varscan2
- NUTM1 | c.2517T>C p.G839= | Silent (SNP) | VAF 26/200 reads (13%) | catalogued as COSV59215925; called by muse, mutect2, varscan2
- OCA2 | c.48G>T p.A16= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV62339720; called by mutect2, varscan2
- OGDHL | c.2487C>T p.R829= | Silent (SNP) | VAF 75/333 reads (23%) | catalogued as rs770634118, COSV65101229; called by muse, mutect2, varscan2
- OR2T10 | c.12C>A p.A4= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as COSV57896231; called by muse, mutect2, varscan2
- OR4C6 | c.393G>C p.T131= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as COSV58602697, COSV58605476; called by muse, mutect2, varscan2
- OR51V1 | c.117C>A p.A39= | Silent (SNP) | VAF 162/684 reads (24%) | catalogued as rs1353950865, COSV58314272; called by muse, mutect2, varscan2
- OR52A1 | c.345C>T p.G115= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100200456, COSV61092033; called by muse, mutect2, varscan2
- PDE1C | c.1329G>T p.T443= | Silent (SNP) | VAF 136/500 reads (27%) | catalogued as COSV100372120, COSV58512533; called by muse, mutect2, varscan2
- PHF3 | c.1056T>C p.N352= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV50313920; called by muse, mutect2
- POLE | c.387A>G p.A129= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV57675062; called by muse, mutect2, varscan2
- RHEBL1 | c.6G>T p.P2= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV56504051; called by muse, mutect2, varscan2
- SIMC1 | c.2172C>A p.I724= (on ENST00000443967 / NM_001308196.1; = p.I309= on NM_198567.5) | Silent (SNP) | VAF 148/219 reads (68%) | catalogued as COSV57900500; called by muse, mutect2, varscan2
- SLC9A1 | c.2005C>A p.R669= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV56051487; called by muse, mutect2, varscan2
- SLIT3 | c.3882C>A p.G1294= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as COSV60594728, COSV60595306; called by muse, mutect2, varscan2
- SZT2 | c.7464T>C p.G2488= (on ENST00000634258 / NM_001365999.1; = p.G2431= on NM_015284.4) | Silent (SNP) | VAF 71/95 reads (75%) | catalogued as COSV65167638; called by muse, mutect2, varscan2
- WRAP53 | c.495C>T p.S165= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs147817526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDHHC9 | c.378C>T p.I126= | Silent (SNP) | VAF 42/616 reads (7%) | catalogued as COSV64096193; called by muse, mutect2
- AC092718.9 | chr16:81154099 G>C | 3'Flank (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- AMFR | c.*323C>A | 3'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99315797; called by muse, mutect2, varscan2
- CDKL1 | n.55G>C | RNA (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.19C>T | RNA (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- LINC01565 | n.1284A>G | RNA (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1809A>G | Intron (SNP) | VAF 66/220 reads (30%) | catalogued as COSV99476355; called by muse, mutect2, varscan2
- SPRR2D | c.-1G>A | 5'UTR (SNP) | VAF 62/238 reads (26%) | catalogued as COSV64209043; called by muse, mutect2, varscan2
